Somatic mutation profile of tumor specimen C3L-07111-04 (aliquot CPT0410990009) from CPTAC case C3L-07111, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 58.8 years (21,488 days).
Specimen C3L-07111-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node(s) Axilla; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 25f404a0-7840-4891-88ef-fff8edeb42a9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-07111-31 (Blood Derived Normal), aliquot CPT0411180003; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/82c7cbdb-d5fb-425d-8e9b-58c7c2e3ad35

The open-access MAF lists 360 somatic variants for this specimen: 238 protein-altering or splice-affecting, 116 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 216, Silent 116, Nonsense Mutation 9, Intron 5, Splice Region 4, Frame Shift Ins 3, In Frame Ins 2, Frame Shift Del 2, Translation Start Site 1, Splice Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 109/255 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- RET | c.1947G>A p.S649= | Silent (SNP) | VAF 208/370 reads (56%) | catalogued as rs377767412, CS962408, COSV60707798; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- RYR2 | c.659G>A p.G220E | Missense Mutation (SNP) | VAF 88/297 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs786205454; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.2242C>T p.L748F | Missense Mutation (SNP) | VAF 141/337 reads (42%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.735); catalogued as COSV70029110; called by muse, mutect2, varscan2
- ACAP3 | c.1739C>T p.S580F | Missense Mutation (SNP) | VAF 157/487 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.246); catalogued as COSV57643042; called by muse, mutect2, varscan2
- AGBL1 | c.1241C>T p.S414F | Missense Mutation (SNP) | VAF 150/473 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV66870300; called by muse, mutect2, varscan2
- ANGPT4 | c.53C>T p.T18I | Missense Mutation (SNP) | VAF 130/412 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.231); catalogued as rs752749565; called by muse, mutect2, varscan2
- ANKIB1 | c.3143C>T p.A1048V | Missense Mutation (SNP) | VAF 94/410 reads (23%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.012); catalogued as rs771646795, COSV56058918; called by muse, mutect2, varscan2
- AOC1 | c.667C>T p.H223Y | Missense Mutation (SNP) | VAF 374/757 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62867934; called by muse, mutect2, varscan2
- APC | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs786202822, COSV57347364; ClinVar: uncertain significance; called by muse, mutect2
- APOL2 | c.804G>A p.M268I | Missense Mutation (SNP) | VAF 378/714 reads (53%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs1314732312; called by muse, mutect2, varscan2
- ATP2B4 | c.1673C>T p.P558L | Missense Mutation (SNP) | VAF 112/350 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.322); catalogued as COSV58176158; called by muse, mutect2, varscan2
- C16orf92 | c.167G>A p.G56E | Missense Mutation (SNP) | VAF 111/409 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV54228433; called by muse, mutect2, varscan2
- C3 | c.3959G>A p.R1320Q | Missense Mutation (SNP) | VAF 75/290 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.692); catalogued as COSV55570849; called by muse, mutect2, varscan2
- CACNA1I | c.1995G>A p.P665= | Splice Region (SNP) | VAF 78/373 reads (21%) | catalogued as rs1344867036; called by muse, mutect2, varscan2
- CBL | c.2486G>A p.R829Q | Missense Mutation (SNP) | VAF 175/351 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs374672276; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- CCDC40 | c.3289C>T p.R1097C | Missense Mutation (SNP) | VAF 163/488 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.505); catalogued as rs769742464; called by muse, mutect2, varscan2
- CD300E | c.352G>A p.D118N | Missense Mutation (SNP) | VAF 73/302 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV60790191; called by muse, mutect2, varscan2
- CD86 | c.950C>T p.S317L (on ENST00000330540 / NM_175862.5; = p.S311L on NM_006889.4) | Missense Mutation (SNP) | VAF 80/260 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs141281931, COSV100053925; called by muse, mutect2, varscan2
- CDH8 | c.2153G>A p.G718D | Missense Mutation (SNP) | VAF 108/433 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.439); catalogued as rs368225592; called by muse, mutect2, varscan2
- CDH8 | c.274G>T p.G92W | Missense Mutation (SNP) | VAF 43/195 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54898248; called by muse, mutect2, varscan2
- CFAP20DC | c.1974A>T p.E658D (on ENST00000482387 / NM_001351530.2; = p.E407D on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 50/200 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.065); catalogued as rs1454529828; called by muse, mutect2, varscan2
- CFAP54 | c.4376C>T p.P1459L | Missense Mutation (SNP) | VAF 64/261 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.139); catalogued as rs989746491; called by muse, mutect2, varscan2
- CHST6 | c.193G>A p.D65N | Missense Mutation (SNP) | VAF 207/610 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.262); catalogued as rs1258235239, COSV100178585, COSV60000809; called by muse, mutect2, varscan2
- COL20A1 | c.2881G>A p.E961K | Missense Mutation (SNP) | VAF 84/288 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.416); catalogued as COSV58924717; called by muse, mutect2, varscan2
- COL22A1 | c.1558G>A p.G520S | Missense Mutation (SNP) | VAF 79/269 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.516); catalogued as COSV57323756; called by muse, mutect2, varscan2
- COL27A1 | c.3494G>A p.G1165E | Missense Mutation (SNP) | VAF 127/269 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.881); catalogued as COSV100621119; called by muse, mutect2, varscan2
- COL5A3 | c.919G>A p.V307I | Missense Mutation (SNP) | VAF 125/382 reads (33%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs139370027; called by muse, mutect2, varscan2
- CYP2C9 | c.35C>T p.S12L | Missense Mutation (SNP) | VAF 168/302 reads (56%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as COSV53246829; called by muse, mutect2, varscan2
- CYP2E1 | c.883G>A p.D295N | Missense Mutation (SNP) | VAF 197/348 reads (57%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.886); catalogued as rs1007026512; called by muse, mutect2, varscan2
- CYP4F11 | c.1379C>T p.P460L | Missense Mutation (SNP) | VAF 52/220 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1330471545; called by muse, mutect2, varscan2
- DCAF8L2 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 186/304 reads (61%) | SIFT deleterious (0.04); PolyPhen benign (0.281); catalogued as rs1189935131; called by muse, varscan2
- DCC | c.841C>T p.Q281* | Nonsense Mutation (SNP) | VAF 73/240 reads (30%) | catalogued as rs1259422937, COSV59083145; called by muse, mutect2, varscan2
- DDX23 | c.1819G>A p.A607T | Missense Mutation (SNP) | VAF 103/378 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99974794; called by muse, mutect2, varscan2
- DNAH2 | c.10195G>A p.A3399T | Missense Mutation (SNP) | VAF 133/410 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.18); catalogued as rs1414004238; called by muse, mutect2, varscan2
- DNAH6 | c.6473G>A p.R2158Q | Missense Mutation (SNP) | VAF 70/259 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.087); catalogued as rs866524152, COSV52853818; called by muse, mutect2, varscan2
- DNAH8 | c.11614C>T p.R3872C | Missense Mutation (SNP) | VAF 48/172 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1362769199; called by muse, varscan2
- DSG1 | c.725G>A p.R242Q | Missense Mutation (SNP) | VAF 87/329 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.586); catalogued as rs1273612156, COSV57133510; called by muse, mutect2, varscan2
- ELOA2 | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 159/514 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs765481551, COSV55300627; called by muse, mutect2, varscan2
- ELOA3C | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 112/1235 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.697); catalogued as rs749201136; called by muse, mutect2, varscan2
- EPHA7 | c.2284C>T p.R762C | Missense Mutation (SNP) | VAF 93/378 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV65179071; called by muse, mutect2, varscan2
- FBN3 | c.4226C>T p.A1409V | Missense Mutation (SNP) | VAF 97/287 reads (34%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs371026092; called by muse, mutect2, varscan2
- FCRL5 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 93/344 reads (27%) | SIFT tolerated (0.91); PolyPhen benign (0.013); catalogued as rs1406891065, COSV62512447, COSV62513927; called by muse, mutect2, varscan2
- FGF9 | c.505G>A p.D169N | Missense Mutation (SNP) | VAF 97/310 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.213); catalogued as rs267603778; called by muse, mutect2, varscan2
- FOLH1 | c.1861G>A p.E621K | Missense Mutation (SNP) | VAF 52/188 reads (28%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV57047661; called by muse, mutect2, varscan2
- FOXJ2 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 67/313 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV50817616; called by muse, mutect2, varscan2
- FSIP2 | c.895dup p.M299Nfs*14 | Frame Shift Ins (INS) | VAF 34/134 reads (25%) | catalogued as rs767378284; called by mutect2, varscan2
- GAB4 | c.1495C>T p.P499S | Missense Mutation (SNP) | VAF 104/539 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as rs1420197690, COSV68753597; called by muse, mutect2, varscan2
- HNF4A | c.1265G>A p.R422Q | Missense Mutation (SNP) | VAF 103/338 reads (30%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as rs202073574, COSV57390196; called by muse, mutect2, varscan2
- ICA1L | c.211G>C p.E71Q | Missense Mutation (SNP) | VAF 46/186 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs747898813, COSV64175324; called by muse, varscan2
- IFNA17 | c.557G>A p.R186K | Missense Mutation (SNP) | VAF 61/147 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.042); catalogued as rs1386730578; called by muse, mutect2, varscan2
- IGDCC3 | c.1291C>G p.R431G | Missense Mutation (SNP) | VAF 128/454 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.268); catalogued as COSV60077058; called by muse, mutect2, varscan2
- IGLV1-44 | c.178C>T p.P60S | Missense Mutation (SNP) | VAF 347/600 reads (58%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.029); catalogued as rs1341746571; called by muse, mutect2, varscan2
- IL37 | c.317G>A p.G106E | Missense Mutation (SNP) | VAF 107/341 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as rs867056062, COSV54492147; called by muse, mutect2, varscan2
- IQSEC1 | c.2711G>A p.R904Q | Missense Mutation (SNP) | VAF 135/471 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as rs138048919; called by muse, mutect2, varscan2
- ITIH1 | c.2200G>A p.G734R | Missense Mutation (SNP) | VAF 138/447 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1249173647; called by muse, mutect2, varscan2
- KDM4E | c.652C>T p.Q218* | Nonsense Mutation (SNP) | VAF 209/428 reads (49%) | catalogued as COSV71678423; called by muse, mutect2, varscan2
- KLK12 | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 291/660 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs925148577, COSV51576518; called by muse, mutect2, varscan2
- LGMN | c.1249C>T p.P417S | Missense Mutation (SNP) | VAF 91/331 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as COSV58402951; called by muse, mutect2, varscan2
- LRP10 | c.869T>C p.V290A | Missense Mutation (SNP) | VAF 152/507 reads (30%) | SIFT tolerated (0.96); PolyPhen benign (0.006); catalogued as rs1485032153; called by muse, mutect2, varscan2
- MARCO | c.332C>T p.S111L | Missense Mutation (SNP) | VAF 104/359 reads (29%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs777128371, COSV100503308; called by muse, mutect2, varscan2
- MGAM2 | c.1504C>T p.P502S | Missense Mutation (SNP) | VAF 80/298 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1563258593; called by muse, mutect2, varscan2
- MGAT5B | c.382G>A p.V128I | Missense Mutation (SNP) | VAF 106/379 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.279); catalogued as rs765506580; called by muse, mutect2, varscan2
- MPHOSPH10 | c.316C>T p.L106F | Missense Mutation (SNP) | VAF 77/302 reads (25%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.477); catalogued as rs1558752009; called by muse, mutect2, varscan2
- MUC16 | c.26111C>T p.S8704F | Missense Mutation (SNP) | VAF 128/420 reads (30%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.631); catalogued as rs866103352, COSV67486445; called by muse, mutect2, varscan2
- MUC16 | c.15355C>T p.P5119S | Missense Mutation (SNP) | VAF 58/258 reads (22%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.471); catalogued as COSV67449282; called by muse, mutect2, varscan2
- MUC3A | c.7895C>T p.P2632L | Missense Mutation (SNP) | VAF 111/720 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs564248922, COSV100115088; called by muse, varscan2
- MX1 | c.401C>T p.S134L | Missense Mutation (SNP) | VAF 106/326 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs375569357; called by muse, mutect2, varscan2
- MYADML2 | c.174G>A p.W58* | Nonsense Mutation (SNP) | VAF 167/503 reads (33%) | catalogued as COSV57999325; called by muse, mutect2, varscan2
- MYH8 | c.4645G>A p.E1549K | Missense Mutation (SNP) | VAF 46/167 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1436914559; called by muse, mutect2, varscan2
- MYO3A | c.2545G>A p.D849N | Missense Mutation (SNP) | VAF 118/219 reads (54%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.531); catalogued as COSV99075845; called by muse, mutect2, varscan2
- NCSTN | c.497C>T p.S166L | Missense Mutation (SNP) | VAF 82/293 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs201886198, CM1414962, COSV54189652; called by muse, mutect2, varscan2
- NINL | c.2413G>A p.E805K | Missense Mutation (SNP) | VAF 181/581 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs745860439; called by muse, mutect2, varscan2
- NOS1 | c.3778C>T p.P1260S | Missense Mutation (SNP) | VAF 110/416 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1330414336; called by muse, mutect2, varscan2
- NUP155 | c.800C>T p.S267F (on ENST00000231498 / NM_153485.3; = p.S208F on NM_004298.4) | Missense Mutation (SNP) | VAF 70/252 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV51527134; called by muse, mutect2, varscan2
- OR10G8 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 119/250 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs745803466, COSV70908204; called by muse, mutect2, varscan2
- OR1M1 | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 105/370 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV70036449; called by muse, mutect2, varscan2
- OR2T10 | c.512C>T p.S171F | Missense Mutation (SNP) | VAF 135/435 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.208); catalogued as COSV57895990; called by muse, mutect2, varscan2
- OR5AC1 | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 20/114 reads (18%) | catalogued as rs1384002782; called by muse, mutect2, varscan2
- OR5D13 | c.297C>A p.C99* | Nonsense Mutation (SNP) | VAF 114/379 reads (30%) | catalogued as COSV62334145; called by muse, mutect2, varscan2
- OR5D13 | c.854C>T p.P285L | Missense Mutation (SNP) | VAF 84/262 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100687058, COSV62332716; called by muse, mutect2, varscan2
- OR5T2 | c.1042C>T p.Q348* | Nonsense Mutation (SNP) | VAF 51/225 reads (23%) | catalogued as COSV57588024, COSV57588589; called by muse, mutect2, varscan2
- OSBP2 | c.2497C>T p.R833C | Missense Mutation (SNP) | VAF 450/821 reads (55%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.901); catalogued as rs776910799, COSV100212512; called by muse, mutect2, varscan2
- PAMR1 | c.1102G>A p.E368K (on ENST00000619888 / NM_001001991.3; = p.E385K on NM_015430.4) | Missense Mutation (SNP) | VAF 98/249 reads (39%) | SIFT tolerated (0.54); PolyPhen benign (0.051); catalogued as COSV53509643; called by muse, mutect2, varscan2
- PASD1 | c.925G>A p.D309N | Missense Mutation (SNP) | VAF 175/292 reads (60%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.708); catalogued as rs1350505912; called by muse, mutect2, varscan2
- PAX4 | c.503G>A p.G168E | Missense Mutation (SNP) | VAF 104/537 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs778775289; called by muse, mutect2, varscan2
- PC | c.2602G>A p.G868R | Missense Mutation (SNP) | VAF 103/403 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58993767; called by muse, mutect2, varscan2
- PCDH15 | c.4856G>C p.R1619T | Missense Mutation (SNP) | VAF 161/334 reads (48%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.028); catalogued as rs1459426728, COSV57330096; called by muse, mutect2, varscan2
- PCDHA7 | c.1042C>A p.P348T | Missense Mutation (SNP) | VAF 37/355 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65341650; called by muse, mutect2, varscan2
- POLG | c.3602C>T p.S1201F | Missense Mutation (SNP) | VAF 98/317 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1567183923; called by muse, mutect2, varscan2
- PRSS21 | c.938C>T p.P313L | Missense Mutation (SNP) | VAF 56/231 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as rs758627036, COSV50051798, COSV99135652; called by muse, mutect2, varscan2
- RNF112 | c.1840G>A p.E614K | Missense Mutation (SNP) | VAF 126/397 reads (32%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.262); catalogued as rs997478101; called by muse, mutect2, varscan2
- RP1 | c.2357G>A p.S786N | Missense Mutation (SNP) | VAF 44/157 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.028); catalogued as COSV55129293; called by muse, mutect2, varscan2
- SALL1 | c.103C>T p.R35C | Missense Mutation (SNP) | VAF 90/337 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs778842406, COSV51757456; called by muse, mutect2, varscan2
- SCN5A | c.3400G>A p.D1134N (on ENST00000333535 / NM_198056.3; = p.D1133N on NM_000335.5) | Missense Mutation (SNP) | VAF 69/241 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.038); catalogued as rs757825178, COSV61119275; called by muse, mutect2, varscan2
- SLC13A3 | c.506G>A p.R169Q | Missense Mutation (SNP) | VAF 117/368 reads (32%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as rs752990690, COSV51712856; called by muse, mutect2, varscan2
- SLC26A5 | c.560G>A p.G187E | Missense Mutation (SNP) | VAF 147/326 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100100247; called by muse, mutect2, varscan2
- SLC28A1 | c.1086C>T p.I362= | Splice Region (SNP) | VAF 79/263 reads (30%) | catalogued as rs377349117; called by muse, mutect2
- SLC5A10 | c.983-6G>A | Splice Region (SNP) | VAF 119/425 reads (28%) | catalogued as rs201146703; called by muse, mutect2, varscan2
- SLITRK4 | c.1760C>T p.P587L | Missense Mutation (SNP) | VAF 132/236 reads (56%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as rs1292818470, COSV62023409; called by muse, mutect2, varscan2
- SMTNL1 | c.818C>T p.P273L (on ENST00000399154; = p.P310L on NM_001105565.2) | Missense Mutation (SNP) | VAF 103/349 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.073); catalogued as COSV67699957; called by muse, mutect2, varscan2
- SOWAHA | c.563C>T p.P188L | Missense Mutation (SNP) | VAF 187/415 reads (45%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs755128478; called by muse, mutect2, varscan2
- SPINT4 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 88/287 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.205); catalogued as rs770970630, COSV54142620; called by muse, varscan2
- SYT5 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 109/565 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs868459585, COSV62831211; called by muse, mutect2, varscan2
- TAFA4 | c.325C>T p.P109S | Missense Mutation (SNP) | VAF 83/250 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs138970524; called by muse, mutect2, varscan2
- TAOK1 | c.1993C>T p.R665C | Missense Mutation (SNP) | VAF 12/428 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1023877006, COSV55595417; called by muse, mutect2
- TAS2R41 | c.574C>T p.P192S | Missense Mutation (SNP) | VAF 94/444 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267601368, COSV68765074; called by muse, mutect2, varscan2
- TBC1D28 | c.316G>A p.V106M | Missense Mutation (SNP) | VAF 98/313 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs1030749957, COSV61507266; called by muse, mutect2, varscan2
- TDRD6 | c.5801C>T p.S1934F | Missense Mutation (SNP) | VAF 116/333 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV60173883; called by muse, mutect2, varscan2
- THSD7B | c.2896C>T p.R966* | Nonsense Mutation (SNP) | VAF 94/374 reads (25%) | catalogued as rs754151775, COSV55729368; called by muse, mutect2, varscan2
- TLE6 | c.650C>T p.S217F (on ENST00000246112 / NM_001143986.2; = p.S94F on NM_024760.3) | Missense Mutation (SNP) | VAF 141/501 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.839); catalogued as rs375278479; called by muse, mutect2, varscan2
- TMEM131L | c.1847C>T p.P616L | Missense Mutation (SNP) | VAF 108/335 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.842); catalogued as rs201534569, COSV53642719; called by muse, mutect2, varscan2
- TNXB | c.10486G>A p.V3496M (on ENST00000647633; = p.V3249M on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 126/380 reads (33%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.469); catalogued as rs376344484; called by muse, mutect2, varscan2
- TP53 | c.874A>C p.K292Q | Missense Mutation (SNP) | VAF 133/476 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as COSV52675742, COSV52676695, COSV53059791; called by muse, mutect2, varscan2
- TPRX1 | c.448C>T p.R150C | Missense Mutation (SNP) | VAF 204/944 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs774935584, COSV59115125; called by muse, mutect2, varscan2
- TRIM71 | c.292G>A p.V98I | Missense Mutation (SNP) | VAF 168/513 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs1424334777; called by muse, mutect2, varscan2
- TTC21B | c.2434C>T p.L812F | Missense Mutation (SNP) | VAF 68/218 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54634799; called by muse, mutect2, varscan2
- TTN | c.16846G>A p.G5616S (on ENST00000591111; = p.G4689S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 94/331 reads (28%) | PolyPhen possibly damaging (0.859); catalogued as rs759141033; called by muse, mutect2, varscan2
- UNC13C | c.4028G>A p.R1343Q | Missense Mutation (SNP) | VAF 77/250 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as rs770064369, COSV52839796, COSV52845310; called by muse, mutect2, varscan2
- VWA5B1 | c.1583C>T p.S528F | Missense Mutation (SNP) | VAF 66/258 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.266); catalogued as rs1192043383, COSV57054403; called by muse, mutect2, varscan2
- WAS | c.1127G>A p.G376E | Missense Mutation (SNP) | VAF 99/152 reads (65%) | SIFT deleterious (0.02); PolyPhen benign (0.36); catalogued as rs1557007227; called by muse, mutect2, varscan2
- WNT9A | c.292C>T p.R98C | Missense Mutation (SNP) | VAF 178/552 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs769516360; called by muse, mutect2, varscan2
- ZGRF1 | c.2009G>A p.R670K | Missense Mutation (SNP) | VAF 68/202 reads (34%) | SIFT tolerated (0.97); PolyPhen benign (0.001); catalogued as rs1196774608; called by muse, mutect2, varscan2
- ZNF157 | c.649C>T p.P217S | Missense Mutation (SNP) | VAF 159/267 reads (60%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.665); catalogued as COSV65659768; called by muse, mutect2, varscan2
- ZNF157 | c.650C>T p.P217L | Missense Mutation (SNP) | VAF 159/266 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs759536811; called by muse, mutect2, varscan2
- ZNF385D | c.164C>T p.A55V | Missense Mutation (SNP) | VAF 53/191 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as rs770545519, COSV55753651, COSV55768121; called by muse, varscan2
- ZPBP2 | c.26C>T p.S9F | Missense Mutation (SNP) | VAF 151/516 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs962310854, COSV53104075; called by muse, mutect2, varscan2
- AGAP1 | c.294G>C p.Q98H | Missense Mutation (SNP) | VAF 110/327 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- AMER3 | c.227G>A p.G76E | Missense Mutation (SNP) | VAF 152/509 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AMER3 | c.2272G>A p.E758K | Missense Mutation (SNP) | VAF 145/553 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.587); called by muse, mutect2, varscan2
- ANK1 | c.3365T>G p.L1122R | Missense Mutation (SNP) | VAF 126/419 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); called by muse, mutect2, varscan2
- ARSH | c.235C>A p.L79M | Missense Mutation (SNP) | VAF 82/143 reads (57%) | SIFT tolerated (0.23); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ASCC3 | c.2785A>G p.N929D | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- BSN | c.5339C>T p.A1780V | Missense Mutation (SNP) | VAF 146/506 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- BUB1 | c.2304A>T p.Q768H | Missense Mutation (SNP) | VAF 63/215 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- C11orf24 | c.512C>T p.S171F | Missense Mutation (SNP) | VAF 174/628 reads (28%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.973); called by muse, varscan2
- C1orf68 | c.613G>A p.G205R | Missense Mutation (SNP) | VAF 138/498 reads (28%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CATSPERB | c.2176G>A p.D726N | Missense Mutation (SNP) | VAF 141/419 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- CDH15 | c.1598G>A p.S533N | Missense Mutation (SNP) | VAF 79/315 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- CEACAM5 | c.565C>T p.P189S | Missense Mutation (SNP) | VAF 149/684 reads (22%) | SIFT tolerated (0.64); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- CHD9 | c.2153T>C p.V718A | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CLDN18 | c.319G>A p.G107S | Missense Mutation (SNP) | VAF 102/539 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CLN8 | c.281A>G p.D94G | Missense Mutation (SNP) | VAF 208/606 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- COL12A1 | c.7639T>A p.F2547I | Missense Mutation (SNP) | VAF 92/309 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- COL6A3 | c.3692A>T p.K1231M | Missense Mutation (SNP) | VAF 50/268 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CPHXL | c.790G>A p.G264R | Missense Mutation (SNP) | VAF 115/443 reads (26%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CRISP3 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 56/217 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CYP2A6 | c.805G>A p.D269N | Missense Mutation (SNP) | VAF 275/567 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DAG1 | c.2275G>T p.V759L | Missense Mutation (SNP) | VAF 131/449 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- DAG1 | c.2276T>A p.V759E | Missense Mutation (SNP) | VAF 130/449 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DOK2 | c.926C>T p.S309F | Missense Mutation (SNP) | VAF 155/580 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- EFR3A | c.827G>T p.C276F | Missense Mutation (SNP) | VAF 69/213 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- EML3 | c.232C>T p.P78S | Missense Mutation (SNP) | VAF 150/556 reads (27%) | SIFT tolerated (0.82); PolyPhen possibly damaging (0.5); called by muse, mutect2
- EPHA4 | c.2395C>T p.R799C | Missense Mutation (SNP) | VAF 89/343 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EPHA6 | c.1847G>A p.G616E | Missense Mutation (SNP) | VAF 104/361 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM83B | c.2578C>T p.P860S | Missense Mutation (SNP) | VAF 101/322 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.188); called by muse, varscan2
- FANCM | c.2002G>A p.G668R | Missense Mutation (SNP) | VAF 51/176 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- FLG2 | c.2893G>A p.G965R | Missense Mutation (SNP) | VAF 158/508 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- FZD5 | c.1484G>C p.R495P | Missense Mutation (SNP) | VAF 175/644 reads (27%) | SIFT tolerated (0.5); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- GUCY1A1 | c.947G>A p.G316E | Missense Mutation (SNP) | VAF 92/347 reads (27%) | SIFT tolerated (0.46); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- HEPHL1 | c.670C>G p.R224G | Missense Mutation (SNP) | VAF 57/149 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- HIVEP2 | c.5612A>C p.E1871A | Missense Mutation (SNP) | VAF 81/277 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- HSD11B1L | c.80T>A p.L27H | Missense Mutation (SNP) | VAF 108/355 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- IGF2BP1 | c.679T>C p.S227P | Missense Mutation (SNP) | VAF 85/333 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, varscan2
- IL12RB1 | c.1784G>A p.G595E | Missense Mutation (SNP) | VAF 133/400 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- IQCN | c.1762C>T p.P588S | Missense Mutation (SNP) | VAF 117/469 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ITGAD | c.1531G>T p.G511C | Missense Mutation (SNP) | VAF 102/339 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITPRID1 | c.2696_2697insAGACAT p.D898_M899insID | In Frame Ins (INS) | VAF 104/283 reads (37%) | called by mutect2, pindel, varscan2
- KDM5C | c.452C>T p.S151F | Missense Mutation (SNP) | VAF 169/249 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- KIR2DL4 | c.772G>A p.G258R (on ENST00000396284; = p.G219R on NM_001080770.2) | Missense Mutation (SNP) | VAF 139/551 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LAMB4 | c.811G>A p.A271T | Missense Mutation (SNP) | VAF 164/662 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LIMK1 | c.46G>A p.G16R | Missense Mutation (SNP) | VAF 108/551 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- LIPI | c.503G>A p.G168D | Missense Mutation (SNP) | VAF 66/223 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LRIT3 | c.1576G>A p.D526N | Missense Mutation (SNP) | VAF 147/439 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- LRP10 | c.733G>A p.D245N | Missense Mutation (SNP) | VAF 146/528 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- LRP10 | c.868G>A p.V290I | Missense Mutation (SNP) | VAF 147/510 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- LRRC4C | c.1675C>T p.H559Y | Missense Mutation (SNP) | VAF 107/428 reads (25%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- MAP1S | c.2620_2621dup p.A875Pfs*136 | Frame Shift Ins (INS) | VAF 161/619 reads (26%) | called by mutect2, pindel, varscan2
- MAST4 | c.3214G>C p.E1072Q (on ENST00000403625 / NM_001164664.2; = p.E883Q on NM_015183.3) | Missense Mutation (SNP) | VAF 134/349 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- MATN2 | c.1784G>A p.G595E | Missense Mutation (SNP) | VAF 101/346 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); called by muse, mutect2
- METTL9 | c.427G>A p.D143N | Missense Mutation (SNP) | VAF 68/272 reads (25%) | SIFT tolerated (0.53); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- MINPP1 | c.937T>A p.L313I | Missense Mutation (SNP) | VAF 57/100 reads (57%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- MNDA | c.451G>A p.V151M | Missense Mutation (SNP) | VAF 108/370 reads (29%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- MYH11 | c.4669G>A p.A1557T | Missense Mutation (SNP) | VAF 162/549 reads (30%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- MYH11 | c.1508G>A p.G503D | Missense Mutation (SNP) | VAF 112/483 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYL5 | c.109G>T p.E37* | Nonsense Mutation (SNP) | VAF 84/271 reads (31%) | called by muse, mutect2, varscan2
- MYO10 | c.764C>T p.P255L | Missense Mutation (SNP) | VAF 66/248 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NAA30 | c.268C>T p.P90S | Missense Mutation (SNP) | VAF 187/630 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NBEAL2 | c.3904C>T p.P1302S | Missense Mutation (SNP) | VAF 159/533 reads (30%) | SIFT tolerated (0.8); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- NDST4 | c.2188G>A p.A730T | Missense Mutation (SNP) | VAF 74/279 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- NDST4 | c.1507G>A p.E503K | Missense Mutation (SNP) | VAF 52/188 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- NEFL | c.1216G>A p.G406R | Missense Mutation (SNP) | VAF 110/352 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); called by muse, varscan2
- NFKB1 | c.910G>A p.D304N (on ENST00000394820 / NM_001382627.1; = p.D305N on NM_003998.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 75/237 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NLRP5 | c.1899G>A p.M633I | Missense Mutation (SNP) | VAF 257/627 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- NTHL1 | c.140A>T p.E47V (on ENST00000219066; = p.E39V on NM_002528.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 86/257 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- OBSCN | c.12808C>T p.Q4270* | Nonsense Mutation (SNP) | VAF 149/481 reads (31%) | called by muse, mutect2, varscan2
- OR11H2 | c.653T>A p.I218N (on ENST00000556246; = p.I229N on NM_001197287.1) | Missense Mutation (SNP) | VAF 81/253 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by mutect2, varscan2
- OR4A16 | c.640A>G p.I214V | Missense Mutation (SNP) | VAF 122/421 reads (29%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- OR8H1 | c.47G>A p.G16E | Missense Mutation (SNP) | VAF 104/338 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- PCDHB2 | c.281G>T p.R94L | Missense Mutation (SNP) | VAF 118/310 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- PCSK5 | c.2684G>A p.C895Y | Missense Mutation (SNP) | VAF 113/265 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PEG10 | c.497T>C p.V166A (on ENST00000482108 / NM_001040152.2; = p.V200A on NM_015068.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 143/601 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PIEZO1 | c.4909_4910del p.L1637Vfs*143 | Frame Shift Del (DEL) | VAF 168/535 reads (31%) | called by pindel, varscan2
- PIGN | c.1183G>T p.D395Y | Missense Mutation (SNP) | VAF 38/174 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.352); called by muse, mutect2
- PLSCR5 | c.808G>A p.G270R | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.1358C>T p.P453L | Missense Mutation (SNP) | VAF 105/392 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.565); called by muse, mutect2, varscan2
- PRDM9 | c.973G>A p.D325N | Missense Mutation (SNP) | VAF 104/392 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- PRKAG1 | c.635C>T p.P212L | Missense Mutation (SNP) | VAF 148/488 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- PRSS37 | c.505G>A p.G169R | Missense Mutation (SNP) | VAF 92/438 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- PRSS53 | c.890G>A p.G297E | Missense Mutation (SNP) | VAF 99/324 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RAPGEF2 | c.442_444dup p.C148dup | In Frame Ins (INS) | VAF 50/484 reads (10%) | called by mutect2, pindel
- RCBTB1 | c.1173G>A p.R391= | Splice Region (SNP) | VAF 83/235 reads (35%) | called by muse, mutect2, varscan2
- RNF113B | c.137G>A p.S46N | Missense Mutation (SNP) | VAF 186/529 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- SEMA3F | c.1745G>A p.R582K | Missense Mutation (SNP) | VAF 92/329 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SETD9 | c.560A>T p.N187I | Missense Mutation (SNP) | VAF 72/160 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- SLC25A27 | c.450dup p.V151Sfs*33 | Frame Shift Ins (INS) | VAF 91/331 reads (27%) | called by mutect2, pindel, varscan2
- SLCO3A1 | c.645A>G p.I215M | Missense Mutation (SNP) | VAF 77/241 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SPN | c.607C>T p.P203S | Missense Mutation (SNP) | VAF 120/409 reads (29%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- STAB1 | c.2932C>T p.P978S | Missense Mutation (SNP) | VAF 185/605 reads (31%) | SIFT tolerated (0.55); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- STXBP6 | c.212C>T p.S71F | Missense Mutation (SNP) | VAF 99/312 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- SV2A | c.1394C>T p.T465I | Missense Mutation (SNP) | VAF 91/324 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- SWT1 | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 84/280 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TACC2 | c.6800T>C p.F2267S (on ENST00000334433; = p.F345S on NM_006997.4) | Missense Mutation (SNP) | VAF 264/413 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TCTN2 | c.2035C>T p.L679F | Missense Mutation (SNP) | VAF 124/385 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TENM4 | c.749+1G>A p.X250_splice | Splice Site (SNP) | VAF 105/249 reads (42%) | called by muse, varscan2
- TENM4 | c.749G>A p.R250K | Missense Mutation (SNP) | VAF 123/271 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TEX14 | c.1114T>C p.F372L (on ENST00000240361 / NM_001201457.2; = p.F366L on NM_031272.5) | Missense Mutation (SNP) | VAF 120/378 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- TMEM125 | c.511G>A p.G171S | Missense Mutation (SNP) | VAF 185/573 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0.44); called by muse, mutect2, varscan2
- TMEM64 | c.329G>A p.R110H | Missense Mutation (SNP) | VAF 54/470 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.586); called by muse, mutect2, varscan2
- TNRC6B | c.1789C>T p.H597Y | Missense Mutation (SNP) | VAF 368/674 reads (55%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- TRAPPC5 | c.542G>A p.R181Q | Missense Mutation (SNP) | VAF 122/319 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- TTN | c.50600G>A p.G16867E (on ENST00000591111; = p.G9443E on NM_003319.4) | Missense Mutation (SNP) | VAF 145/413 reads (35%) | PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UHRF1BP1L | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 62/203 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- USP28 | c.2742C>A p.Y914* | Nonsense Mutation (SNP) | VAF 31/155 reads (20%) | called by muse, mutect2, varscan2
- ZFR2 | c.2338G>A p.A780T | Missense Mutation (SNP) | VAF 113/388 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF329 | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 87/342 reads (25%) | SIFT tolerated (0.67); PolyPhen benign (0.001); called by muse, varscan2
- ZNF592 | c.3763del p.S1255Lfs*55 | Frame Shift Del (DEL) | VAF 136/492 reads (28%) | called by pindel, varscan2
- ZNF66 | c.1394C>T p.S465F | Missense Mutation (SNP) | VAF 55/218 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ZNF831 | c.2648C>T p.S883F | Missense Mutation (SNP) | VAF 183/601 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- AADACL3 | c.769C>T p.L257= | Silent (SNP) | VAF 86/436 reads (20%) | catalogued as COSV60199008; called by muse, mutect2
- ADAM2 | c.1806G>A p.R602= | Silent (SNP) | VAF 49/145 reads (34%) | catalogued as COSV55861261; called by muse, mutect2, varscan2
- ADCY7 | c.903G>A p.V301= | Silent (SNP) | VAF 64/262 reads (24%) | called by muse, mutect2, varscan2
- AGO1 | c.1773C>T p.F591= | Silent (SNP) | VAF 117/353 reads (33%) | catalogued as rs775325449, COSV64595099; called by muse, mutect2, varscan2
- AKAP8 | c.1191C>T p.F397= | Silent (SNP) | VAF 66/289 reads (23%) | catalogued as rs1328901813; called by muse, mutect2, varscan2
- AKT3 | c.549C>T p.V183= | Silent (SNP) | VAF 65/176 reads (37%) | called by muse, mutect2, varscan2
- AMER3 | c.228G>A p.G76= | Silent (SNP) | VAF 155/512 reads (30%) | called by muse, mutect2, varscan2
- ANKFN1 | c.988C>T p.L330= | Silent (SNP) | VAF 63/220 reads (29%) | called by muse, mutect2, varscan2
- ASB18 | c.255C>T p.A85= | Silent (SNP) | VAF 119/349 reads (34%) | called by muse, mutect2, varscan2
- ATP2A2 | c.2502C>T p.F834= | Silent (SNP) | VAF 80/268 reads (30%) | catalogued as COSV57875420; called by muse, mutect2, varscan2
- ATP2B3 | c.1156C>T p.L386= | Silent (SNP) | VAF 143/237 reads (60%) | called by muse, mutect2, varscan2
- C1orf210 | c.42C>T p.L14= | Silent (SNP) | VAF 124/414 reads (30%) | catalogued as rs1466960049; called by muse, mutect2, varscan2
- C6 | c.201G>A p.K67= | Silent (SNP) | VAF 112/340 reads (33%) | catalogued as COSV54711535; called by muse, mutect2, varscan2
- CCDC158 | c.1497G>A p.S499= | Silent (SNP) | VAF 115/356 reads (32%) | catalogued as rs764729163; called by muse, mutect2, varscan2
- CCDC68 | c.285A>C p.I95= | Silent (SNP) | VAF 55/214 reads (26%) | called by muse, mutect2, varscan2
- CDH23 | c.7218C>T p.S2406= | Silent (SNP) | VAF 157/284 reads (55%) | called by muse, mutect2, varscan2
- CEP350 | c.8481G>A p.E2827= | Silent (SNP) | VAF 80/260 reads (31%) | called by muse, mutect2, varscan2
- CILP | c.2142C>T p.F714= | Silent (SNP) | VAF 127/353 reads (36%) | called by muse, mutect2, varscan2
- CLDN24 | c.108C>T p.L36= | Silent (SNP) | VAF 123/397 reads (31%) | called by muse, mutect2, varscan2
- CLYBL | c.87C>T p.I29= | Silent (SNP) | VAF 79/251 reads (31%) | called by muse, mutect2, varscan2
- CNGB1 | c.3111G>A p.G1037= | Silent (SNP) | VAF 92/332 reads (28%) | called by muse, mutect2, varscan2
- COL4A4 | c.3318C>T p.G1106= | Silent (SNP) | VAF 97/326 reads (30%) | called by muse, mutect2, varscan2
- COL5A1 | c.2607C>T p.V869= | Silent (SNP) | VAF 99/264 reads (38%) | catalogued as rs558625072, COSV65673103; called by muse, mutect2, varscan2
- COL6A3 | c.3693G>A p.K1231= | Silent (SNP) | VAF 51/269 reads (19%) | catalogued as rs559076376; called by muse, mutect2, varscan2
- CRB1 | c.2592C>T p.F864= | Silent (SNP) | VAF 106/349 reads (30%) | catalogued as COSV66329292, COSV66331692; called by muse, mutect2, varscan2
- CWH43 | c.1155T>G p.L385= | Silent (SNP) | VAF 58/169 reads (34%) | called by muse, mutect2, varscan2
- CYP2C19 | c.1299G>T p.R433= | Silent (SNP) | VAF 87/166 reads (52%) | catalogued as COSV64907833; called by muse, mutect2, varscan2
- DCAF4 | c.501C>T p.S167= | Silent (SNP) | VAF 71/287 reads (25%) | called by muse, mutect2, varscan2
- DCC | c.1431G>A p.L477= | Silent (SNP) | VAF 75/255 reads (29%) | catalogued as COSV100499766, COSV59096757; called by muse, mutect2, varscan2
- DCDC1 | c.597G>A p.L199= | Silent (SNP) | VAF 92/290 reads (32%) | catalogued as rs1280859639; called by muse, mutect2
- DNAH17 | c.1017G>A p.Q339= | Silent (SNP) | VAF 60/249 reads (24%) | catalogued as COSV101104132; called by muse, mutect2, varscan2
- DOK2 | c.927C>T p.S309= | Silent (SNP) | VAF 152/576 reads (26%) | called by muse, mutect2, varscan2
- DRD5 | c.438C>T p.F146= | Silent (SNP) | VAF 131/465 reads (28%) | called by muse, mutect2, varscan2
- DSCAM | c.1752C>T p.S584= | Silent (SNP) | VAF 101/371 reads (27%) | called by muse, mutect2, varscan2
- ELOA3B | c.777G>A p.P259= | Silent (SNP) | VAF 82/1642 reads (5%) | called by muse, mutect2
- EPHA8 | c.387G>A p.S129= | Silent (SNP) | VAF 140/466 reads (30%) | catalogued as COSV51262387, COSV51282460; called by muse, mutect2, varscan2
- EXOC3L1 | c.543G>A p.G181= | Silent (SNP) | VAF 158/435 reads (36%) | catalogued as COSV99333591; called by muse, mutect2, varscan2
- FBXL18 | c.819C>T p.F273= | Silent (SNP) | VAF 298/646 reads (46%) | catalogued as rs1427761747; called by muse, mutect2, varscan2
- FMO5 | c.402G>T p.G134= | Silent (SNP) | VAF 116/452 reads (26%) | catalogued as rs782086011; called by muse, mutect2, varscan2
- FOXC1 | c.390C>G p.L130= | Silent (SNP) | VAF 142/498 reads (29%) | called by muse, mutect2, varscan2
- GATA4 | c.891C>T p.L297= | Silent (SNP) | VAF 128/374 reads (34%) | called by muse, mutect2, varscan2
- GRB7 | c.669C>T p.F223= | Silent (SNP) | VAF 117/339 reads (35%) | catalogued as rs760291966; called by muse, mutect2, varscan2
- GRHL1 | c.558C>T p.F186= | Silent (SNP) | VAF 159/494 reads (32%) | catalogued as rs267598794, COSV61406900; called by muse, mutect2, varscan2
- GRIN2A | c.4071C>T p.L1357= | Silent (SNP) | VAF 140/416 reads (34%) | catalogued as COSV58053487, COSV58056456; called by muse, mutect2, varscan2
- GRM3 | c.723C>T p.I241= | Silent (SNP) | VAF 300/658 reads (46%) | catalogued as rs923538983, COSV64469476; called by muse, mutect2, varscan2
- HYAL3 | c.420C>T p.G140= | Silent (SNP) | VAF 185/517 reads (36%) | called by muse, mutect2, varscan2
- IGSF22 | c.24G>A p.Q8= | Silent (SNP) | VAF 106/334 reads (32%) | called by muse, mutect2, varscan2
- IKZF2 | c.324G>A p.P108= | Silent (SNP) | VAF 136/394 reads (35%) | catalogued as rs868111109, COSV59583799; called by muse, mutect2, varscan2
- ITGA2B | c.69T>C p.P23= | Silent (SNP) | VAF 155/488 reads (32%) | catalogued as COSV52234902; called by muse, mutect2, varscan2
- ITPR2 | c.6585C>T p.D2195= | Silent (SNP) | VAF 59/254 reads (23%) | catalogued as rs754042777; called by muse, mutect2, varscan2
- KCNB1 | c.978G>A p.R326= | Silent (SNP) | VAF 165/547 reads (30%) | catalogued as COSV65568144; called by muse, mutect2, varscan2
- KCNK15 | c.264C>T p.I88= | Silent (SNP) | VAF 86/299 reads (29%) | catalogued as rs760420269; called by muse, mutect2, varscan2
- KLHL28 | c.1224C>A p.P408= | Silent (SNP) | VAF 82/301 reads (27%) | called by mutect2, varscan2
- KRT76 | c.594C>T p.I198= | Silent (SNP) | VAF 75/238 reads (32%) | catalogued as rs1042625698; called by muse, mutect2, varscan2
- KRTAP4-9 | c.471C>T p.S157= | Silent (SNP) | VAF 230/781 reads (29%) | called by muse, varscan2
- LMO7 | c.4890C>T p.A1630= (on ENST00000357063; = p.A1311= on NM_005358.5) | Silent (SNP) | VAF 53/188 reads (28%) | called by muse, mutect2, varscan2
- LRP10 | c.1404C>T p.A468= | Silent (SNP) | VAF 87/326 reads (27%) | catalogued as rs775740510; called by muse, mutect2, varscan2
- LRP1B | c.8619C>T p.D2873= | Silent (SNP) | VAF 64/248 reads (26%) | catalogued as COSV101257404; called by muse, mutect2, varscan2
- MAN1C1 | c.879G>A p.P293= | Silent (SNP) | VAF 56/529 reads (11%) | catalogued as rs371000685; called by muse, mutect2
- MAN2C1 | c.2118C>T p.S706= | Silent (SNP) | VAF 106/354 reads (30%) | called by muse, mutect2, varscan2
- MROH2B | c.381C>T p.F127= | Silent (SNP) | VAF 116/350 reads (33%) | catalogued as COSV68181409, COSV68187898; called by muse, mutect2, varscan2
- MSH4 | c.1056T>C p.R352= | Silent (SNP) | VAF 72/175 reads (41%) | called by muse, mutect2, varscan2
- MUC16 | c.23460G>A p.R7820= | Silent (SNP) | VAF 112/425 reads (26%) | catalogued as COSV67445089; called by muse, mutect2, varscan2
- MYH8 | c.1503G>A p.Q501= | Silent (SNP) | VAF 113/423 reads (27%) | called by muse, mutect2, varscan2
- MYO7B | c.1251C>T p.A417= | Silent (SNP) | VAF 118/419 reads (28%) | called by muse, mutect2, varscan2
- NAIF1 | c.867C>T p.L289= | Silent (SNP) | VAF 186/355 reads (52%) | called by muse, mutect2, varscan2
- NDUFB6 | c.72G>A p.K24= | Silent (SNP) | VAF 154/316 reads (49%) | catalogued as COSV63083142; called by muse, mutect2, varscan2
- NIPAL3 | c.1215G>A p.K405= | Silent (SNP) | VAF 80/294 reads (27%) | catalogued as rs770841962; called by muse, mutect2, varscan2
- NOVA2 | c.102C>T p.F34= | Silent (SNP) | VAF 86/400 reads (22%) | catalogued as COSV54359939; called by muse, mutect2, varscan2
- NRG1 | c.1095C>G p.S365= (on ENST00000405005 / NM_013964.5; = p.S370= on NM_013956.5) | Silent (SNP) | VAF 92/267 reads (34%) | catalogued as COSV99829776; called by muse, mutect2, varscan2
- OBSCN | c.15489G>A p.G5163= | Silent (SNP) | VAF 137/496 reads (28%) | catalogued as COSV52784139; called by muse, mutect2, varscan2
- OBSCN | c.15960C>T p.I5320= | Silent (SNP) | VAF 152/470 reads (32%) | called by muse, mutect2, varscan2
- OLFML2B | c.2124C>T p.I708= | Silent (SNP) | VAF 112/358 reads (31%) | catalogued as rs1339107894, COSV54195870; called by muse, varscan2
- OR14I1 | c.111G>A p.L37= | Silent (SNP) | VAF 160/501 reads (32%) | catalogued as rs774385927; called by muse, mutect2
- OR2M5 | c.183C>T p.F61= | Silent (SNP) | VAF 118/472 reads (25%) | catalogued as COSV63546300; called by muse, mutect2, varscan2
- OR4K2 | c.897G>A p.R299= | Silent (SNP) | VAF 33/123 reads (27%) | catalogued as rs1291478184, COSV53848607, COSV53849458; called by muse, mutect2
- OR5T3 | c.291C>T p.F97= | Silent (SNP) | VAF 121/411 reads (29%) | catalogued as COSV57381624; called by muse, mutect2, varscan2
- PARVB | c.627C>T p.V209= | Silent (SNP) | VAF 206/412 reads (50%) | catalogued as rs761863085; called by muse, mutect2, varscan2
- PDE11A | c.1209G>A p.L403= | Silent (SNP) | VAF 82/255 reads (32%) | catalogued as rs964290743; called by muse, mutect2, varscan2
- PKHD1L1 | c.5208G>A p.Q1736= | Silent (SNP) | VAF 124/388 reads (32%) | catalogued as COSV65749593; called by muse, mutect2, varscan2
- PNOC | c.192C>T p.V64= | Silent (SNP) | VAF 149/438 reads (34%) | called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.1359C>T p.P453= | Silent (SNP) | VAF 104/393 reads (26%) | catalogued as rs1357792556; called by muse, mutect2, varscan2
- RABEPK | c.255C>T p.P85= | Silent (SNP) | VAF 86/198 reads (43%) | catalogued as COSV52337519, COSV99413586; called by muse, mutect2, varscan2
- RASGRF2 | c.2733G>A p.R911= | Silent (SNP) | VAF 81/178 reads (46%) | catalogued as COSV54133592; called by muse, mutect2, varscan2
- RBMXL2 | c.192C>T p.A64= | Silent (SNP) | VAF 156/502 reads (31%) | catalogued as rs1276142982, COSV100182289; called by muse, mutect2, varscan2
- REXO5 | c.1620C>T p.T540= | Silent (SNP) | VAF 82/263 reads (31%) | called by muse, mutect2, varscan2
- RGS11 | c.396C>A p.I132= (on ENST00000397770 / NM_183337.3; = p.I111= on NM_003834.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 106/381 reads (28%) | catalogued as COSV51452509; called by muse, mutect2, varscan2
- RIPOR2 | c.3009C>T p.I1003= | Silent (SNP) | VAF 69/265 reads (26%) | called by muse, mutect2, varscan2
- RNF20 | c.2523C>T p.A841= | Silent (SNP) | VAF 110/245 reads (45%) | called by muse, mutect2, varscan2
- SCN7A | c.3975C>T p.S1325= | Silent (SNP) | VAF 29/131 reads (22%) | called by muse, mutect2, varscan2
- SHANK2 | c.3597G>A p.G1199= | Silent (SNP) | VAF 178/351 reads (51%) | catalogued as COSV53600876; called by muse, mutect2, varscan2
- SLCO2A1 | c.360C>T p.F120= | Silent (SNP) | VAF 96/320 reads (30%) | catalogued as rs1051260404, COSV60489716; called by muse, mutect2, varscan2
- SLITRK6 | c.1761T>G p.P587= | Silent (SNP) | VAF 123/437 reads (28%) | called by muse, mutect2, varscan2
- SMYD1 | c.765C>T p.F255= | Silent (SNP) | VAF 143/467 reads (31%) | called by muse, mutect2
- SPNS3 | c.420C>T p.F140= | Silent (SNP) | VAF 114/341 reads (33%) | called by muse, mutect2, varscan2
- STK11 | c.1035C>T p.H345= | Silent (SNP) | VAF 54/442 reads (12%) | catalogued as rs751619208; ClinVar: benign / likely benign; called by muse, mutect2, varscan2
- STK33 | c.315G>A p.R105= | Silent (SNP) | VAF 55/176 reads (31%) | catalogued as rs267603222, COSV59404471; called by muse, mutect2, varscan2
- TEX2 | c.2136G>A p.S712= | Silent (SNP) | VAF 101/276 reads (37%) | catalogued as rs764773178, COSV51982866; called by muse, mutect2, varscan2
- TFIP11 | c.1212C>T p.F404= | Silent (SNP) | VAF 141/807 reads (17%) | catalogued as rs1008468686; called by muse, mutect2, varscan2
- TLCD3B | c.354G>A p.T118= | Silent (SNP) | VAF 105/416 reads (25%) | catalogued as rs373625205; called by muse, mutect2, varscan2
- TMEM260 | c.1467C>T p.N489= | Silent (SNP) | VAF 109/355 reads (31%) | called by muse, mutect2, varscan2
- TNR | c.600G>A p.S200= | Silent (SNP) | VAF 142/459 reads (31%) | catalogued as rs142283399; called by muse, mutect2, varscan2
- TNRC6B | c.1788A>T p.T596= | Silent (SNP) | VAF 369/676 reads (55%) | called by muse, mutect2, varscan2
- TRAPPC12 | c.456C>T p.P152= | Silent (SNP) | VAF 188/595 reads (32%) | catalogued as rs779167794; called by muse, mutect2, varscan2
- TRAPPC3L | c.402G>A p.G134= | Silent (SNP) | VAF 81/274 reads (30%) | catalogued as rs1038488850; called by muse, mutect2, varscan2
- TRIM9 | c.1710G>A p.G570= | Silent (SNP) | VAF 192/548 reads (35%) | called by muse, mutect2, varscan2
- TRIT1 | c.9C>T p.S3= | Silent (SNP) | VAF 103/322 reads (32%) | catalogued as rs946338022, COSV100381576; called by muse, mutect2, varscan2
- TSSK1B | c.681C>T p.I227= | Silent (SNP) | VAF 124/267 reads (46%) | called by muse, mutect2, varscan2
- TYW1 | c.528A>G p.V176= | Silent (SNP) | VAF 95/464 reads (20%) | catalogued as rs1312963034; called by muse, mutect2, varscan2
- UBASH3A | c.480C>T p.F160= | Silent (SNP) | VAF 138/480 reads (29%) | catalogued as rs146176015; called by muse, mutect2, varscan2
- WDR81 | c.4989C>T p.F1663= (on ENST00000409644 / NM_001163809.2; = p.F612= on NM_152348.4) | Silent (SNP) | VAF 253/722 reads (35%) | catalogued as rs148436740; called by muse, mutect2, varscan2
- XAB2 | c.1401C>T p.A467= | Silent (SNP) | VAF 81/258 reads (31%) | catalogued as rs773292866; called by muse, mutect2, varscan2
- ZMYND8 | c.81T>C p.H27= (on ENST00000311275 / NM_001363741.2; = p.H47= on NM_012408.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 162/481 reads (34%) | called by muse, mutect2, varscan2
- ZNF233 | c.420C>A p.P140= | Silent (SNP) | VAF 72/405 reads (18%) | called by muse, mutect2, varscan2
- ZNF727 | c.1128C>T p.T376= | Silent (SNP) | VAF 220/489 reads (45%) | catalogued as COSV70702243; called by muse, mutect2, varscan2
- ASAH2 | c.510+2671C>T | Intron (SNP) | VAF 146/266 reads (55%) | catalogued as rs1214179015; called by muse, mutect2, varscan2
- FNDC3B | c.188-40136G>T | Intron (SNP) | VAF 85/200 reads (43%) | called by muse, mutect2, varscan2
- KLHL5 | c.2211+11C>T | Intron (SNP) | VAF 113/405 reads (28%) | catalogued as rs1476823939; called by muse, mutect2, varscan2
- MRTFA | c.601+35G>A | Intron (SNP) | VAF 441/795 reads (55%) | called by muse, mutect2, varscan2
- PIF1 | c.*502C>T | 3'UTR (SNP) | VAF 159/482 reads (33%) | called by muse, mutect2, varscan2
- TTN | c.34354+794C>T | Intron (SNP) | VAF 8/32 reads (25%) | called by mutect2, varscan2
